FM case AD7038 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/7226cc69-76d6-4346-9498-c3cc8bca0fd0

Female, 46.3 years: Carcinoma, NOS (ICD-O-3 8010/3) of the ovary; metastasis biopsied or resected from the colon. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
